Gene-level copy-number profile of tumor specimen TCGA-EY-A547-01A from TCGA case TCGA-EY-A547, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 75.8 years (27,686 days).
Specimen TCGA-EY-A547-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.e4de0a98-89c9-4439-af6d-acb4e5cb08a3.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EY-A547-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/094e5862-43fa-44ae-a8ca-53b87d53a310

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 13,685; copy number 2: 39,191; copy number 3: 4,240; copy number 4: 725; copy number 5: 1,531; copy number 6: 40; copy number 7: 97; copy number 8: 166; copy number 9: 70; copy number 10: 25; copy number 12: 13; copy number 17: 29; copy number 21: 1.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EY-A547-01A-11D-A27O-01): tumor purity 0.98, ploidy 1.99, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,972 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:58,198–13,032,886, 248 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr5:42,729,138–44,658,569, 46 genes, copy number 9–17 (within-gene range 4–17): AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1, PAIP1, NNT-AS1, AC010435.1, AMD1P3, NNT, RPL29P12, AC104119.1, RNU6-381P, FGF10, FGF10-AS1, LINC02224.
- chr7:65,617,082–66,811,189, 41 genes, copy number 6–12 (within-gene range 1–12): AC104057.1, AC073107.1, INTS4P2, CCT6P1, SNORA22, SNORA15B-2, AC073107.2, GTF2IP5, RNU6-912P, AC093582.1, RNU6-973P, VKORC1L1, GUSB, AC073261.1, AC068533.2, AC068533.1, ASL, AC068533.4, CRCP, AC068533.3, TPST1, RNU6-313P, LINC00174, GTF2IP9, SKP1P1, AC008267.2, AC008267.4, AC008267.7, AC008267.5, AC008267.6, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5, KCTD7, AC027644.4, AC006001.2.
- chr8:36,784,324–36,936,125, 1 gene, copy number 5 (within-gene range 3–5): KCNU1.
- chr8:36,887,456–38,973,912, 63 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).
- chr8:69,987,415–145,066,685, 1,176 genes, copy number 5 (broad region; genes not listed).
- chr14:40,267,283–40,348,331, 1 gene, copy number 6: AL049828.2.
- chr18:30,290,161–35,145,417, 75 genes, copy number 7–21 (broad region; genes not listed).
- chr20:31,303,212–33,731,828, 97 genes, copy number 5–9 (broad region; genes not listed).
- chr20:36,996,349–37,095,997, 1 gene, copy number 7 (within-gene range 4–7): RBL1.
- chr20:37,049,254–38,337,505, 33 genes, copy number 7 (within-gene range 1–7): RPS27AP3, AL136172.1, MROH8, AL031659.1, RPN2, GHRH, MANBAL, AL034422.1, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI.
- chr20:42,968,743–47,786,616, 166 genes, copy number 8 (within-gene range 1–8) (broad region; genes not listed).
- chr20:52,840,936–54,173,986, 24 genes, copy number 10 (within-gene range 1–10): AL161945.1, AL121902.1, RPL36P1, TSHZ2, RN7SKP184, AL391097.3, AL391097.1, AL391097.2, AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1, BCAS1, AC005220.1, MIR4756, CYP24A1.

Autosomal genes at a single copy (total copy number 1): 13,163. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
